Somatic mutation profile of tumor specimen TARGET-10-PATPGE-09A (aliquot TARGET-10-PATPGE-09A-01D) from TARGET case TARGET-10-PATPGE, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 19.7 years (7,204 days).
Specimen TARGET-10-PATPGE-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01e1db10-c337-4027-9df0-c7c6120b25bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATPGE-10A (Blood Derived Normal), aliquot TARGET-10-PATPGE-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b56ac8b-1b79-4ecc-ae26-fea604b8d6b7

The open-access MAF lists 24 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 4, RNA 2, Frame Shift Ins 2, 3'Flank 1, Intron 1, In Frame Del 1, 3'UTR 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD34 | c.209C>G p.T70S | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.051); catalogued as COSV60413624; called by muse, mutect2, varscan2
- DDB1 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57102944; called by muse, mutect2, varscan2
- DDX39B | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63331536; called by muse, mutect2, varscan2
- DRC3 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1213494692, COSV58264067; called by muse, mutect2, varscan2
- GAPDHS | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); catalogued as COSV55882930; called by muse, mutect2, varscan2
- IGLV3-16 | c.147del p.K49Nfs*17 | Frame Shift Del (DEL) | VAF 44/114 reads (39%) | catalogued as rs746629447; called by mutect2, pindel, varscan2
- MYOCD | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 63/120 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs552203360, COSV58496778; called by muse, mutect2, varscan2
- NOTCH1 | c.4583G>T p.C1528F | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53060149, COSV53062582; called by muse, mutect2, varscan2
- NUTM2F | c.1615C>T p.P539S | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.22); PolyPhen benign (0.201); catalogued as COSV53558079; called by muse, mutect2, varscan2
- ZNF536 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1445915532, COSV100834810, COSV62826243; called by muse, varscan2
- IGHV3-43 | c.351_354delinsGATG p.D118M | Missense Mutation (ONP) | VAF 29/113 reads (26%) | called by pindel, varscan2*
- PTEN | c.685_699delinsAAGAAT p.S229_R233delinsKN | In Frame Del (DEL) | VAF 21/70 reads (30%) | called by pindel, varscan2*
- SULT1A2 | c.390dup p.N131Qfs*64 | Frame Shift Ins (INS) | VAF 20/55 reads (36%) | called by mutect2, varscan2
- SULT1A2 | c.388dup p.R130Pfs*65 | Frame Shift Ins (INS) | VAF 15/58 reads (26%) | called by mutect2*, pindel, varscan2*
- CHD5 | c.3714C>T p.H1238= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as rs368027040, COSV99312236; called by muse, mutect2, varscan2
- DTNA | c.2088G>A p.T696= | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as rs374444921; called by muse, mutect2, varscan2
- PTCH1 | c.3840G>A p.S1280= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs750770371, COSV59472126; ClinVar: likely benign; called by muse, mutect2, varscan2
- RBKS | c.954G>A p.P318= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as rs749621448; called by muse, mutect2, varscan2
- AFDN | chr6:167976167 C>G | 3'Flank (SNP) | VAF 6/20 reads (30%) | catalogued as rs77867907; called by mutect2, varscan2
- GPC5 | c.*38C>T | 3'UTR (SNP) | VAF 15/39 reads (38%) | catalogued as rs190929028, COSV100993475; called by muse, mutect2, varscan2
- HYDIN2 | n.4514G>T | RNA (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2, varscan2
- ITGB1 | c.2331+25C>T | Intron (SNP) | VAF 27/59 reads (46%) | catalogued as rs1377823390; called by muse, mutect2, varscan2
- PDE4A | chr19:10417841 C>A | 5'Flank (SNP) | VAF 21/60 reads (35%) | catalogued as COSV100764067; called by muse, mutect2, varscan2
- RRN3P3 | n.1060C>T | RNA (SNP) | VAF 4/41 reads (10%) | catalogued as rs200715642; called by muse, varscan2
